Gene-level copy-number profile of tumor specimen MP2PRT-PAPFFT-TMP1-A from MP2PRT case MP2PRT-PAPFFT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,514 days).
Specimen MP2PRT-PAPFFT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83eb6ec3-f44b-4c71-bff5-b9ca8535681f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPFFT-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/204de449-0be1-490d-ac71-014c3b7f8007

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 536; copy number 1: 11,883; copy number 2: 45,528; copy number 3: 866; copy number 4: 89.

Homozygous deletions (total copy number 0; autosomes only): 428 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,918,107–159,925,507, 1 gene: TAGLN2.
- chr1:160,997,957–161,045,977, 4 genes (within-gene range 0–2): AL591806.2, GLRX5P2, TSTD1, USF1.
- chr1:228,073,909–228,182,257, 12 genes: LINC02809, ARF1, MIR3620, C1orf35, MRPL55, FAM96AP2, AL359510.2, AL359510.1, GUK1, GJC2, IBA57-DT, IBA57.
- chr2:37,562,486–37,646,698, 1 gene (within-gene range 0–2): AC006369.1.
- chr2:43,219,849–43,233,394, 4 genes (within-gene range 0–2): AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:177,111,036–177,212,662, 1 gene (within-gene range 0–2): AC079305.2.
- chr2:177,177,695–177,223,958, 5 genes: STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1.
- chr2:177,229,191–177,265,515, 3 genes (within-gene range 0–2): DNAJC19P5, MIR3128, AC079305.1.
- chr3:157,146,508–157,174,040, 5 genes: CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146.
- chr5:132,410,636–132,488,702, 1 gene: IRF1-AS1.
- chr5:132,419,416–132,490,777, 4 genes: LINC02863, Y_RNA, AC116366.1, IRF1.
- chr6:159,669,069–159,789,703, 9 genes: SOD2, HNRNPH1P1, RNU4ATAC18P, WTAP, SOD2-OT1, ACAT2, TCP1, SNORA20, SNORA29.
- chr7:38,239,580–38,378,804, 23 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:112,422,887–112,490,941, 4 genes (within-gene range 0–2): IFRD1, AC079741.1, AC005192.1, AC079741.2.
- chr7:142,626,649–142,802,748, 36 genes (within-gene range 0–2): TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr9:137,551,879–137,615,360, 4 genes: MRPL41, DPH7, ZMYND19, ARRDC1.
- chr9:137,615,332–137,618,906, 1 gene: ARRDC1-AS1.
- chr10:11,168,922–11,171,376, 1 gene (within-gene range 0–2): AL136320.1.
- chr10:102,394,110–102,436,584, 5 genes: NFKB2, PSD, FBXL15, CUEDC2, MIR146B.
- chr11:62,559,596–62,888,875, 50 genes: EEF1G, AP002990.1, MIR6747, TUT1, MTA2, EML3, AP001458.1, ROM1, B3GAT3, GANAB, INTS5, AP001458.2, C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1, LRRN4CL, BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C, ZBTB3, POLR2G, AP001160.2, TAF6L, TMEM223, AP001160.3, TMEM179B, MIR6748, NXF1, MIR6514, STX5, AP001160.4, RNU6-118P, AP001160.1, TEX54, WDR74, RNU2-2P, SNHG1, SNORD22, SNORD30, SNORD22, SNORD28, SNORD27, SNORD26, SNORD25, SLC3A2.
- chr11:64,185,272–64,357,534, 25 genes: STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155.
- chr12:12,248,991–12,724,011, 18 genes (within-gene range 0–1): AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1.
- chr14:22,163,238–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,836,765–106,108,464, 60 genes (within-gene range 0–1): IGHD, IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.
- chr16:28,097,976–28,211,965, 4 genes (within-gene range 0–2): XPO6, TPRKBP2, AC136611.1, RNY1P10.
- chr18:76,978,827–77,133,683, 6 genes (within-gene range 0–2): MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2.
- chr19:39,306,566–39,428,415, 10 genes: LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2.
- chr22:36,281,280–36,396,517, 4 genes (within-gene range 0–2): MYH9, MIR6819, Z82215.1, FO393418.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
